Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-AB27, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-AB27-01A (Primary Tumor).

[page 1 of 5]
ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
J 4/25/14

Accession Date:

Collection Date:

FINAL DIAGNOSIS:

PART 1: PELVIC LYMPH NODES, RIGHT, DISSECTION -

A. TEN BENIGN LYMPH NODES (0/10).

B. NEGATIVE FOR MALIGNANCY.

PART 2: PELVIC LYMPH NODES, LEFT, DISSECTION -

A. FIVE BENIGN LYMPH NODES (0/5), INCLUDING ONE LYMPH NODE WITH PROMINENT MACROPHAGES CONTAINING COARSELY GRANULAR PIGMENT (Slide 2A-2B).

B. NEGATIVE FOR MALIGNANCY.

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

A. INVASIVE PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE $3 + 3 = 6$ WITH A MINOR GLEASON PATTERN 4 COMPONENT COMPRISING LESS THAN 5% OF THE EXAMINED TUMOR VOLUME (Slide 3Z).

B. CARCINOMA INVOLVES BOTH RIGHT LOBE (APEX THROUGH BASE) AND LEFT LOBE (APEX).

C. CARCINOMA HAS A MAXIMAL NODULAR DIAMETER OF 1 CM (Slide 3AB).

D. CARCINOMA INVOLVES APPROXIMATELY 5% OF THE EXAMINED PROSTATE VOLUME.

E. CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.

F. NO PERINEURAL INVASION IS IDENTIFIED.

G. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.

H. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.

I. BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA ARE FREE OF CARCINOMA.

J. ALL FINAL SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA (See also Part 4).

K. BACKGROUND PROSTATIC PARENCHYMA WITH MILD NODULAR HYPERPLASIA, GLANDULAR ATROPHY, AND

MILD CHRONIC INFLAMMATION.

L. PATHOLOGIC STAGE (AJCC 7th EDITION): pT2c, N0, Mx.

M. HISTOLOGIC GRADE (AJCC 7th EDITION): G2 (See synoptic).

PART 4: URETHRAL MARGIN, APEX, DISSECTION -

A. BENIGN FIBROMUSCULAR PERIURETHRAL TISSUE AND FEW BENIGN DISTORTED GLANDS (? PROSTATIC).

[page 2 of 5]
Anonymous No.:

Age: 68

Gender: M

Race: Black

CLINICAL HISTORY

The patient is a 68-year-old man with a serum PSA value of 7.94 ng/mL. He had a prostate biopsy on [REDACTED]; this biopsy revealed prostatic adenocarcinoma, Gleason score 3+ 3 = 6, in the right medial, right apex and right lateral apex of the prostate.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy and bilateral pelvic lymph node dissection.

FINAL DIAGNOSIS

PART 1: PELVIC LYMPH NODES, RIGHT, DISSECTION

- A. TEN BENIGN LYMPH NODES (0/10).
- B. NEGATIVE FOR MALIGNANCY.

PART 2: PELVIC LYMPH NODES, LEFT, DISSECTION

- A. FIVE BENIGN LYMPH NODES (0/5), INCLUDING ONE LYMPH NODE WITH PROMINENT MACROPHAGES CONTAINING COARSELY GRANULAR PIGMENT (Slide 2A-2B).
- B. NEGATIVE FOR MALIGNANCY.

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY

- A. INVASIVE PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3 + 3 = 6 WITH A MINOR GLEASON PATTERN 4 COMPONENT COMPRISING LESS THAN 5% OF THE EXAMINED TUMOR VOLUME (Slide 3Z).
- B. CARCINOMA INVOLVES BOTH RIGHT LOBE (APEX THROUGH BASE) AND LEFT LOBE (APEX).
- C. CARCINOMA HAS A MAXIMAL NODULAR DIAMETER OF 1 CM (Slide 3AB).
- D. CARCINOMA INVOLVES APPROXIMATELY 5% OF THE EXAMINED PROSTATE VOLUME.
- E. CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- F. NO PERINEURAL INVASION IS IDENTIFIED.
- G. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- H. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- I. BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA ARE FREE OF CARCINOMA.
- J. ALL FINAL SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA (See also Part 4).
- K. BACKGROUND PROSTATIC PARENCHYMA WITH MILD NODULAR HYPERPLASIA, GLANDULAR ATROPHY, AND MILD CHRONIC INFLAMMATION.
- L. PATHOLOGIC STAGE (AJCC 7th EDITION): pT2c, N0, Mx.
- M. HISTOLOGIC GRADE (AJCC 7th EDITION): G2 (See synoptic).

PART 4: URETHRAL MARGIN, APEX, DISSECTION

- A. BENIGN FIBROMUSCULAR PERIURETHRAL TISSUE AND FEW BENIGN DISTORTED GLANDS (? PROSTATIC).
- B. NEGATIVE FOR NEOPLASIA.

COMMENT

[page 3 of 5]
{Not Entered}

GROSS DESCRIPTION

Part 1 is labeled with the patient's name, initials [REDACTED] medical record number and "1 right pelvic lymph nodes".

Specimen Received: Fresh

Type of Specimen Received: 6.5 x 3.2 x 1.2 cm in aggregate, portions of yellow lobulated fibroadipose tissue.

Dissection: Ten potential right pelvic lymph nodes.

Measurements: Range in measure from 0.2 x 0.1 x 0.1 cm to 3.4 x 1.8 x 0.7 cm.

Tissue SNAP frozen for possible future studies: No.

Block Summary:

1A-1B - single potential lymph node, bisected

1C - single lymph node, bisected

1D - two lymph nodes

1E - two lymph nodes

1F - four lymph nodes

1G - remaining tissue

Formalin Exposure Time: 101 hours 30 minutes

Part 2 is labeled with the patient's name, initials [REDACTED] medical record number and "2 left pelvic lymph nodes".

Specimen Received: Fresh

Type of Specimen Received: 4.7 x 2.4 x 1.0 cm in aggregate, portions of yellow lobulated fibroadipose tissue.

Dissection: Five potential left pelvic lymph nodes.

Measurements: Range in measure from 0.2 x 0.2 x 0.1 cm to 2.8 x 2.0 x 1.0 cm.

Tissue SNAP frozen for possible future studies: No.

Block Summary:

2A-2B - single potential lymph node, bisected

2C - single potential lymph node, bisected

2D - single potential lymph node, bisected

2E - two lymph nodes

2F - remaining tissue.

Formalin Exposure Time: 101 hours 30 minutes

Part 3 is labeled with the patient's name, initials [REDACTED] medical record number and "3 prostate".

Specimen Received: Fresh

Type of Specimen Received: Slightly distorted and surgically disrupted prostate gland with attached seminal vesicles and segments of vas deferens.

[page 4 of 5]
Weight of Specimen: 29.15 g.

Size of Specimen:

Prostate:

Right to Left: 4.0 cm.

Apex to Base: 3.5 cm.

Anterior to Posterior: 3.0cm.

Seminal Vesicles:

Right: 1.2 x 0.5 x 0.5 cm.

Left: 1.2 x 1.0 x 0.5 cm.

Vas Deferens:

Right: 0.8 cm length, 0.5 cm diameter.

Left: 1.0cm length, 0.5 cm diameter.

Orientation:

Right Side: Black ink.

Left Side: Orange ink.

Gross Description of Prostate:

Urethra: Probe patent: Yes.

Capsule: Stripped: Yes.

Sutured vascular ligation on anterior surface: 4.0 x 0.5 cm (positioned right to left at distal urethra margin).

Number of Levels: 4 (distal to proximal).

Lesion Description:

Proximal Urethral Margin: Grossly unremarkable.

Distal Urethral Margin (not true margin: see part 4): Grossly unremarkable.

Anterior Capsule: Grossly unremarkable.

Posterior Capsule: Grossly unremarkable.

Cut Surface of Levels: Multiple confluent nodules consistent with BPH identified in all levels.
No discrete lesions identified.

Seminal Vesicles: Grossly unremarkable.

Other Notable Features: No stones are present.

Digital Photograph Taken: No.

Tissue SNAP frozen for possible future studies: Yes, levels 2 and 3.

Description of Other Organs or Structures: N/A.

Block Summary:

The following sections are submitted:

3A - base of right seminal vesicle and vas deferens

3B - right vas deferens margin

3C - base of left seminal vesicle and vas deferens

[page 5 of 5]
3D - left vas deferens margin

3E-3H - proximal urethral margin, radially sectioned (3E = right anterior, 3F = right posterior, 3G = left anterior, 3H = left posterior)

3I-3L - distal urethral margin, radially sectioned (not true margin: see part 4) (3I = right anterior, 3J = right posterior, 3K = left

anterior, 3L = left posterior)

3M - capsule, anterior right apex

3N - capsule, anterior right mid

3O - capsule, anterior right base

3P - capsule, anterior left apex

3Q - capsule, anterior left mid

3R-3S - capsule, anterior left base

3T - capsule, posterior right apex

3U - capsule, posterior right mid

3V - capsule, posterior right base

3W - capsule, posterior left apex

3X - capsule, posterior left mid

3Y - capsule, posterior left base

3Z - level 1, right

3AA - level 1, left

3AB - level 4, right anterior

3AC - level 4, right posterior

3AD - level 4, left anterior

3AE - level 4, left posterior.

Formalin Exposure Time: 101 hours 30 minutes

Part 4 is labeled with the patient's name, initials [REDACTED], medical record number and "4 urethra apical margin".

Specimen Received: Fresh

Type of Specimen Received: Three un-oriented pieces of firm pale tan to tan tissue.

Measurements: Range in measure from 0.7 x 0.6 x 0.3 cm to 1.4 x 1.1 x 0.6 cm

Digital Photograph Taken: No.

Tissue SNAP frozen for possible further studies: No.

Block Summary:

4A - specimen entirely submitted

Formalin Exposure Time: 101 hours 30 minutes

Grossed by: [REDACTED]

MICROSCOPIC DESCRIPTION

{Not Entered}

INTRAOPERATIVE DIAGNOSIS

{Not Entered}

Source: NCI Genomic Data Commons file 2237f961-ad8d-491b-a220-a2f66105fa47 (TCGA-EJ-AB27.83FBE69E-525B-4833-BD10-AE4360BFF925.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).